Surgical pathology report (de-identified scan), TCGA case TCGA-08-0354, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0354-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA - 08 - 0354

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left frontal lobe, biopsy: WHO glioblastoma multiforme, grade IV; see comment.
- B. Brain, left frontal lobe #2, biopsy: WHO glioblastoma multiforme, grade IV; see comment.
- C. Brain, left frontal lobe, resection: No tumor identified; see comment.

COMMENT: The initial sections submitted, those from Parts A and B, show a highly cellular astrocytic neoplasm with mitoses, foci of microvascular proliferation and foci of necrosis. These findings support a diagnosis of glioblastoma multiforme. Immunohistochemistry for GFAP and neurofilament, performed and examined on blocks A2 and B2 to establish the diagnosis, show GFAP positive neoplastic astrocytes in a background of neurofilament positive axons. Immunohistochemistry for MIB-1 will be performed on block B2 and the results will be reported in an addendum.

The additional brain tissue submitted, the majority of which was sampled and evaluated (22 cassettes), show gray and white matter with foci of hemorrhage consistent with surgical effect. A population of infiltrating neoplastic glial cells is not identified in these tissue sections.

Intraoperative Diagnosis

- FS1 (A) Left frontal lobe, biopsy: Glial neoplasm with focal necrosis and pleomorphism. Probable glioblastoma multiforme. Tissue section and cytologic preparation. [REDACTED]
- FS2 (B) Left frontal cortex, biopsy: Favor glioblastoma multiforme. [REDACTED] agrees. Tissue section and cytologic preparation. [REDACTED]

Gross Description

[page 2 of 2]
The specimen is received from the O.R. in three parts, each labeled with the patient's name and medical record number. Parts A and B are received fresh. Part C is received in formalin.

Part A is additionally labeled "L frontal lobe," and consists of multiple tan fragments measuring in aggregate 1.0 x 0.6 x 0.2 cm. A portion is submitted for frozen section diagnosis 1 and resubmitted in cassette A1. The non-frozen remaining tissue is submitted in cassette A2.

Part B is additionally labeled "2 - L frontal lobe FS," and consists of one 0.8 x 0.6 x 0.2 cm, tan, soft tissue fragment. A portion is submitted for frozen section diagnosis 2 and resubmitted in cassette B1. The remaining non-frozen tissue is submitted in cassette B2.

Part C, labeled "frontal lobe tumor," consists of multiple fragments of cortex measuring 4.0 x 3.0 x 2.0 cm in aggregate. Sectioning reveals extensive areas of red-brown discoloration, which probably represent hemorrhage. Representative sections are submitted as follows:

Cassettes C1-C15: Piece 1, with apparent hemorrhage, totally embedded.

Cassette C16: Second piece, one-half submitted.

Cassette C17-C22: Third piece, grossly normal brain, representative sections.

Clinical History

The patient is a [REDACTED] who presents with a [REDACTED] peripherally enhancing mass in the left frontal cortex. She has had no prior therapy.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

ADDENDUM

Date of Addendum: [REDACTED]

Addendum Comment

A reticulin stain on block B2 is negative for features of gliosarcoma.

ADDENDUM

Date of Addendum: [REDACTED]

Addendum Comment

The MIB-1 immunohistochemical labelling is 20.06%.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED] Medical Center Department of Pathology. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high-complexity clinical testing.

Source: NCI Genomic Data Commons file 57ef13c6-1372-4c44-b688-25da3bbd074e (TCGA-08-0354.A232EB0B-0B9F-495F-8165-4C73D5B71964.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).